Somatic mutation profile of tumor specimen 0DI3NG from CCDI case PBBVCK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.7 years (1,726 days).
Specimen 0DI3NG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adb3c387-8349-47ad-b911-9733b323ca43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI3JE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c94e74ef-4406-4634-9ca5-73b4b7087c40

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HERC2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 193/514 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs200667217, COSV55341928; called by muse, varscan2
- DLL1 | c.1410G>A p.P470= | Silent (SNP) | VAF 191/546 reads (35%) | catalogued as rs529134000; called by muse, varscan2
